Gene-level copy-number profile of tumor specimen HCM-CSHL-0374-C25-01A from HCMI case HCM-CSHL-0374-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 74.7 years (27,272 days).
Specimen HCM-CSHL-0374-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 143c2dda-a03b-441f-aab2-94176fa82734.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0374-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/1cea4af3-7129-4e3e-ab0d-fceacad53c96

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 461; copy number 1: 9,379; copy number 2: 42,838; copy number 3: 5,312; copy number 4: 673; copy number 5: 171; copy number 6: 61; copy number 7: 5; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:9,053,816–9,053,895, 1 gene (within-gene range 0–2): MIR4636.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 242 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:39,299,001–39,934,551, 10 genes, copy number 5: KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1.
- chr6:40,391,591–44,380,179, 144 genes, copy number 5 (broad region; genes not listed).
- chr6:44,513,262–45,377,953, 4 genes, copy number 5 (within-gene range 1–5): AL136140.1, AL136140.2, AL133334.1, SUPT3H.
- chr6:45,097,496–45,664,349, 7 genes, copy number 5: AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr19:30,037,285–31,427,302, 14 genes, copy number 5–8: TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr19:34,994,784–35,066,571, 5 genes, copy number 7 (within-gene range 4–7): GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN.
- chr19:39,863,323–41,018,398, 58 genes, copy number 6: FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2, AC008537.1, CYP2T1P, CYP2F2P, AC008537.2, AC008537.3, CYP2A6, CYP2A7, CYP2G1P, CYP2A7P2, CYP2B7P, AC092071.1, CYP2B6.

Autosomal genes at a single copy (total copy number 1): 8,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
